Somatic mutation profile of cancer-model specimen HCM-WCMC-1280-C54-85A (3D Organoid; aliquot HCM-WCMC-1280-C54-85A-01D-A905-36), derived from the primary tumor of HCMI case HCM-WCMC-1280-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 63.1 years (23,032 days).
Specimen HCM-WCMC-1280-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3349ba0-35b6-4f03-b67f-17532e03ec8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1280-C54-10A (Blood Derived Normal), aliquot HCM-WCMC-1280-C54-10A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cb03470-65f4-48eb-b3c0-00ad2595b94d

The open-access MAF lists 105 somatic variants for this specimen: 80 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 24, Nonsense Mutation 6, In Frame Del 2, Frame Shift Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT9 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 170/288 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519957, COSV55299607; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- JAG1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 258/522 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918351, CM981095, CM992632, COSV54757968; ClinVar: pathogenic; called by muse, varscan2
- PIK3R1 | c.1746-1G>C p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 129/129 reads (100%) | hotspot (GDC flag); catalogued as COSV57125628, COSV57128950, COSV99163201; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 208/360 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 255/255 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ZAP70 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 295/448 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113994174, CM015398, COSV53854464; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 69/108 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV53789451; called by muse, mutect2, varscan2
- ANKS6 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs899298265; called by muse, mutect2, varscan2
- ARMCX2 | c.324G>C p.Q108H | Missense Mutation (SNP) | VAF 87/556 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1556066725, COSV57529995, COSV57530880; called by muse, mutect2, varscan2
- ASH1L | c.3580G>T p.D1194Y | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV64204965, COSV99054583; called by muse, mutect2
- ASZ1 | c.682C>G p.H228D | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1429440064, COSV52914693, COSV99497734; called by muse, mutect2, varscan2
- B4GALNT1 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.506); catalogued as rs767768866, COSV57543059; called by muse, mutect2, varscan2
- CTNNA1 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs766845544; called by muse, mutect2, varscan2
- DDX58 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 89/250 reads (36%) | catalogued as rs750416435; called by muse, mutect2, varscan2
- DST | c.21899G>A p.R7300Q (on ENST00000361203 / NM_001374722.1; = p.R4973Q on NM_015548.5) | Missense Mutation (SNP) | VAF 397/649 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs768734906; called by muse, mutect2, varscan2
- ECEL1 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 364/536 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1184780729; called by muse, mutect2, varscan2
- EPB41L3 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 88/161 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778271797, COSV59466978; called by muse, mutect2, varscan2
- EVC | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs767013073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFRA2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 270/554 reads (49%) | SIFT tolerated (0.89); PolyPhen benign (0.026); catalogued as rs1302420484, COSV60778522; called by muse, mutect2, varscan2
- LRCH2 | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); catalogued as COSV57746395; called by muse, mutect2, varscan2
- MARCKSL1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 302/1039 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs1319159995; called by muse, mutect2, varscan2
- OGG1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV57354537; called by muse, mutect2, varscan2
- OR1C1 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101376187, COSV101376201; called by muse, mutect2, varscan2
- PCDHA11 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 439/741 reads (59%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); catalogued as rs782454963, COSV56484438; called by muse, mutect2, varscan2
- PCDHGA9 | c.1373C>G p.S458* | Nonsense Mutation (SNP) | VAF 65/304 reads (21%) | catalogued as rs762306578; called by muse, mutect2, varscan2
- PCDHGB6 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 115/482 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1228341286; called by muse, mutect2, varscan2
- PCDHGB7 | c.2407C>G p.L803V | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53917843; called by muse, mutect2, varscan2
- PDE7B | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 114/173 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs1054707702; called by muse, mutect2, varscan2
- PFAS | c.2230G>A p.V744M | Missense Mutation (SNP) | VAF 300/300 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs866028921, COSV58980718; called by muse, mutect2, varscan2
- PTEN | c.809T>C p.M270T | Missense Mutation (SNP) | VAF 63/66 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as CM165144, COSV64296995; called by muse, mutect2, varscan2
- RMDN2 | c.864C>G p.F288L (on ENST00000354545 / NM_001322212.2; = p.F466L on NM_144713.5) | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs763187680; called by muse, mutect2, varscan2
- SCN1A | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as rs1275890918; called by muse, mutect2, varscan2
- SGK1 | c.1100_1102del p.K367del | In Frame Del (DEL) | VAF 74/134 reads (55%) | catalogued as rs1562235584; called by pindel, varscan2
- SIPA1L1 | c.4625A>G p.K1542R | Missense Mutation (SNP) | VAF 194/350 reads (55%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1261414540; called by muse, mutect2, varscan2
- SLC4A2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 143/478 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.089); catalogued as rs749981018, COSV59658658; called by muse, mutect2, varscan2
- SLCO1C1 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 176/260 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99859653; called by muse, mutect2, varscan2
- TRPC3 | c.685C>T p.R229C (on ENST00000379645 / NM_001366479.2; = p.R156C on NM_003305.2) | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53375600; called by muse, mutect2, varscan2
- ZNF185 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 179/484 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs1215013521; called by muse, mutect2, varscan2
- ZNF791 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 86/785 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); catalogued as rs746552226, COSV58482365; called by muse, mutect2, varscan2
- ADAMTS20 | c.2282G>A p.S761N | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP000812.4 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BSDC1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 234/791 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH12 | c.7546G>A p.D2516N (on ENST00000351747; = p.D3384N on NM_001366028.2) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- DNAJC18 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- EPHX2 | c.1205G>A p.S402N | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAN1 | c.998G>T p.W333L | Missense Mutation (SNP) | VAF 118/378 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAN1 | c.999G>A p.W333* | Nonsense Mutation (SNP) | VAF 114/374 reads (30%) | called by muse, mutect2, varscan2
- HACE1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HGH1 | c.477_486del p.R160Afs*14 | Frame Shift Del (DEL) | VAF 800/1065 reads (75%) | called by mutect2, pindel, varscan2
- IGSF9B | c.2162G>C p.R721P | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); called by muse, mutect2
- JAGN1 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.385); called by muse, mutect2
- KIF17 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHDC8B | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 132/535 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KNTC1 | c.3013G>C p.D1005H | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LPP | c.1529A>G p.D510G | Missense Mutation (SNP) | VAF 197/755 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- MBTPS1 | c.1608del p.Y537Ifs*32 | Frame Shift Del (DEL) | VAF 40/185 reads (22%) | called by mutect2, pindel, varscan2
- MIS18A | c.165G>C p.M55I | Missense Mutation (SNP) | VAF 68/528 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEFM | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 54/543 reads (10%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.986); called by muse, mutect2
- NSUN3 | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 77/371 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA10 | c.788C>A p.T263N | Missense Mutation (SNP) | VAF 114/448 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PCDHGA10 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 107/457 reads (23%) | called by muse, mutect2, varscan2
- PRPF8 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PSME4 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 446/446 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PSME4 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 448/448 reads (100%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- QTRT1 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 246/1921 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RBM15 | c.841C>G p.R281G | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RCBTB2 | c.1449C>G p.I483M | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- REPS2 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RRNAD1 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.366); called by muse, varscan2
- SEC24B | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SFXN5 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SUPT20H | c.1108T>C p.C370R (on ENST00000350612 / NM_001014286.3; = p.C371R on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM69 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 243/373 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TUBGCP4 | c.372C>G p.Y124* | Nonsense Mutation (SNP) | VAF 83/287 reads (29%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.216T>A p.F72L | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBXN1 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- VPS13D | c.9195_9203del p.R3065_D3067del | In Frame Del (DEL) | VAF 122/217 reads (56%) | called by mutect2, pindel, varscan2
- WIF1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF878 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 56/549 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ZXDB | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 324/449 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ABAT | c.888G>A p.Q296= | Silent (SNP) | VAF 210/397 reads (53%) | catalogued as rs1379134544; called by muse, mutect2, varscan2
- ACTN2 | c.1725C>T p.I575= | Silent (SNP) | VAF 89/403 reads (22%) | catalogued as COSV100856606; called by muse, mutect2, varscan2
- ADGRL1 | c.3006C>T p.Y1002= (on ENST00000340736 / NM_001008701.3; = p.Y997= on NM_014921.5) | Silent (SNP) | VAF 226/753 reads (30%) | called by muse, mutect2, varscan2
- ALK | c.3138C>T p.A1046= | Silent (SNP) | VAF 42/410 reads (10%) | catalogued as rs747588801, COSV101202682; ClinVar: likely benign; called by muse, mutect2
- ARHGEF11 | c.1422C>T p.F474= | Silent (SNP) | VAF 82/342 reads (24%) | catalogued as rs763483544, COSV63812691; called by muse, mutect2, varscan2
- CFAP47 | c.6201G>A p.E2067= | Silent (SNP) | VAF 37/170 reads (22%) | called by muse, mutect2, varscan2
- COL6A6 | c.1942C>T p.L648= | Silent (SNP) | VAF 184/363 reads (51%) | called by muse, mutect2, varscan2
- CORO1B | c.291C>G p.V97= | Silent (SNP) | VAF 55/279 reads (20%) | called by muse, mutect2, varscan2
- DCUN1D3 | c.162C>T p.N54= | Silent (SNP) | VAF 107/403 reads (27%) | catalogued as rs749220210, COSV60953132; called by muse, mutect2, varscan2
- DNAAF2 | c.1548G>A p.K516= | Silent (SNP) | VAF 290/554 reads (52%) | called by muse, mutect2, varscan2
- HEXIM2 | c.24C>T p.T8= | Silent (SNP) | VAF 24/354 reads (7%) | catalogued as rs186910629; called by muse, mutect2
- LAMA5 | c.7255C>T p.L2419= | Silent (SNP) | VAF 58/410 reads (14%) | called by muse, varscan2
- LRP10 | c.1365C>T p.L455= | Silent (SNP) | VAF 19/491 reads (4%) | called by muse, mutect2
- NEIL3 | c.693C>G p.L231= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV99220140; called by muse, mutect2, varscan2
- OR2L3 | c.324T>C p.G108= | Silent (SNP) | VAF 52/402 reads (13%) | called by muse, varscan2
- PCDHGA10 | c.267C>T p.I89= | Silent (SNP) | VAF 144/571 reads (25%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.462C>T p.L154= | Silent (SNP) | VAF 97/422 reads (23%) | catalogued as rs769641711; called by muse, mutect2, varscan2
- PCGF2 | c.606G>T p.L202= | Silent (SNP) | VAF 214/346 reads (62%) | called by muse, mutect2, varscan2
- PON1 | c.21C>T p.L7= | Silent (SNP) | VAF 89/302 reads (29%) | called by muse, varscan2
- PPP2R5E | c.822C>T p.V274= | Silent (SNP) | VAF 49/282 reads (17%) | catalogued as rs112894962, COSV61741233; called by muse, mutect2, varscan2
- SCARB1 | c.699C>T p.L233= | Silent (SNP) | VAF 155/156 reads (99%) | catalogued as rs757891509; called by muse, mutect2, varscan2
- SEC16B | c.1053G>A p.Q351= | Silent (SNP) | VAF 92/407 reads (23%) | catalogued as rs781178697; called by muse, mutect2, varscan2
- SPO11 | c.81G>C p.L27= | Silent (SNP) | VAF 127/480 reads (26%) | called by muse, mutect2, varscan2
- UNC5D | c.828C>T p.S276= | Silent (SNP) | VAF 245/531 reads (46%) | catalogued as COSV54817832; called by muse, mutect2, varscan2
- CCDC107 | chr9:35657867 C>T | 5'Flank (SNP) | VAF 117/397 reads (29%) | catalogued as rs1278840803, CR155848; called by muse, mutect2
